TCGA case TCGA-DX-A48R — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a37238f3-55b5-43df-a0c5-3d22ee5156f3

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 41 years; Vital status: Alive.

Diagnoses (2)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 41.4 years (15,107 days); Year of diagnosis: 2002; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Sites of involvement: Pelvic Vein, Common, External or Iliac; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 9.5; Tumor length measurement: 18; Tumor width measurement: 14.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 23.
   Pathology details: Measurement type: Pathologic; Tumor burden: 45.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 3; Tumor width measurement: 1.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 1; Tumor width measurement: 0.4.
2. Recurrence of diagnosis 1 (Leiomyosarcoma, NOS), site: Liver. Age at diagnosis: 42.2 years (15,422 days); Days to diagnosis: 315 days; Prior treatment: Yes.

Follow-up (3 entries)
- Day 315 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 315 days.
- Day 315 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 315 days.
- Days to follow up: 805 days (2.2 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A48R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 450 mg.
  Slide TCGA-DX-A48R-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 1.
- Sample TCGA-DX-A48R-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A48R-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: Pelvic vein,common,external, or iliac; Margin status: Positive; Disease multifocal indicator: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Primary pathology, Tumor sizes, Tumor size 1: Lesion pathologic length: 3.0; Lesion pathologic width: 1.0.
- Primary pathology, Tumor sizes, Tumor size 2: Lesion pathologic length: 1.0.
- Primary pathology, Tumor sizes, Tumor size 3: Lesion pathologic length: 23.0.
- Primary pathology, Tumor sizes, Tumor size 4: Lesion pathologic length: 18.0.
- Follow-up form 1: Lost to follow-up: Yes; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 805 days; disease-specific survival: no event (censored), 805 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 315 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A48R-01A-11D-A306-01): tumor purity 0.97, ploidy 1.82, whole-genome doublings 0.
